Somatic mutation profile of tumor specimen 0DHPK4 from CCDI case PBBSWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.9 years (6,543 days).
Specimen 0DHPK4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9547949-cbac-4fe2-8c51-c507cd7f20e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHPJA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/398e9648-8d0c-423a-b562-14d524ac9b13

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 3, In Frame Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.11095_11097del p.N3699del | In Frame Del (DEL) | VAF 145/684 reads (21%) | catalogued as rs781549554; called by mutect2, varscan2
- ENDOU | c.320A>G p.N107S (on ENST00000422538 / NM_001172439.2; = p.N66S on NM_006025.4) | Missense Mutation (SNP) | VAF 240/952 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs765765315; called by muse, mutect2, varscan2
- GALNT1 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 131/590 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1376983118; called by muse, mutect2, varscan2
- SULT4A1 | c.742+7G>A | Splice Region (SNP) | VAF 73/279 reads (26%) | called by muse, mutect2, varscan2
- USP10 | c.2090G>A p.C697Y | Missense Mutation (SNP) | VAF 33/1114 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AGER | c.1042C>T p.L348= | Silent (SNP) | VAF 157/699 reads (22%) | catalogued as rs749487080; called by muse, mutect2, varscan2
- FBXW8 | c.16C>T p.L6= | Silent (SNP) | VAF 66/315 reads (21%) | called by muse, mutect2, varscan2
- GRIN2A | c.3846C>T p.N1282= | Silent (SNP) | VAF 26/824 reads (3%) | called by muse, mutect2
- OR10Q1 | c.951C>T p.D317= | Silent (SNP) | VAF 44/765 reads (6%) | catalogued as rs980926586, COSV57470822; called by muse, mutect2
- PRDM9 | c.2274C>T p.R758= | Silent (SNP) | VAF 81/1118 reads (7%) | called by muse, mutect2
- SLC38A3 | c.1254C>T p.I418= | Silent (SNP) | VAF 32/686 reads (5%) | called by muse, mutect2
- TYW1B | c.-80T>C | 5'UTR (SNP) | VAF 75/346 reads (22%) | catalogued as COSV70479361; called by muse, mutect2, varscan2
